Somatic mutation profile of tumor specimen TCGA-BJ-A0Z2-01A (aliquot TCGA-BJ-A0Z2-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0Z2, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Follicular adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 57.5 years (21,008 days).
Specimen TCGA-BJ-A0Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbaf7ff2-33b1-47a6-a177-43207f1bf481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0Z2-10A (Blood Derived Normal), aliquot TCGA-BJ-A0Z2-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf2db513-d2c7-4ff7-9f10-bbfab2149f72

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 5'Flank 2, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 65/173 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA2D1 | c.2584G>A p.A862T (on ENST00000356253 / NM_001366867.1; = p.A850T on NM_000722.4) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62381742; called by muse, mutect2, varscan2
- IRF5 | c.1489A>T p.M497L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV50856845; called by muse, mutect2, varscan2
- MUC16 | c.32174C>G p.P10725R | Missense Mutation (SNP) | VAF 181/419 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV67450083, COSV67459342; called by muse, mutect2, varscan2
- MUC5B | c.15431A>T p.D5144V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV71590414; called by muse, mutect2, varscan2
- NANS | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV52963146; called by muse, mutect2, varscan2
- NEXMIF | c.1056T>G p.S352R | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV50022892; called by muse, mutect2
- NLRP3 | c.343T>C p.W115R | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60221025; called by muse, mutect2, varscan2
- PDE3A | c.2422A>T p.N808Y | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV62969174; called by muse, mutect2, varscan2
- PRKD1 | c.2343C>G p.F781L | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV59560801, COSV59590376; called by muse, mutect2, varscan2
- PTK2B | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57751086; called by muse, mutect2, varscan2
- UBR4 | c.13903G>T p.V4635L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); catalogued as COSV64383747; called by muse, mutect2, varscan2
- CACNA2D1 | c.2585C>A p.A862E (on ENST00000356253 / NM_001366867.1; = p.A850E on NM_000722.4) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRRT | c.43_66del p.K15_D22del | In Frame Del (DEL) | VAF 48/141 reads (34%) | called by mutect2, pindel, varscan2
- SUOX | c.412del p.A138Pfs*23 | Frame Shift Del (DEL) | VAF 88/239 reads (37%) | called by mutect2, pindel, varscan2
- PIK3C2A | c.2463T>C p.P821= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV56400809; called by muse, mutect2
- SNRNP27 | c.9C>T p.R3= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs1465839193, COSV54911123; called by muse, mutect2, varscan2
- WEE2 | c.840A>T p.A280= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as COSV66878339; called by muse, mutect2, varscan2
- ZNF652 | c.1623G>T p.R541= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV62946338; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502510 del TTGT | 5'Flank (DEL) | VAF 12/34 reads (35%) | catalogued as rs1368903038; called by mutect2, pindel
- SLC5A1 | chr22:32039511 C>T | 5'Flank (SNP) | VAF 43/51 reads (84%) | catalogued as rs771227042; called by muse, mutect2, varscan2
- VPS13B | c.4820+15637A>T | Intron (SNP) | VAF 30/68 reads (44%) | catalogued as COSV100660825; called by muse, mutect2, varscan2
